CPTAC case C3L-03735 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5b45cc31-9f54-4838-a44c-fbbbcbdb3ef2

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Year of birth: 1944; Vital status: Dead; Days to death: 1,323 days (3.6 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 74.1 years (27,073 days); Year of diagnosis: 2018; Last known disease status: With tumor; Days to last known disease status: 1,323 days (3.6 years); Progression or recurrence: yes; Days to recurrence: 267 days; Days to last follow up: 1,315 days (3.6 years).
   Pathology details: Greatest tumor dimension: 2 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (4 entries)
- Days to follow up: 523 days (1.4 years); Karnofsky performance status: 80.
- Days to follow up: 1,062 days (2.9 years); Progression or recurrence: Yes; Days to recurrence: 267 days.
- Days to follow up: 1,315 days (3.6 years); Disease response: With Tumor; Karnofsky performance status: 50.
- Follow-up contact recording only the day: day 740.

Other clinical attributes
- Weight: 87 kg; Height: 177.8 cm; BMI: 27.52.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-03735-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 300 mg; Time between excision and freezing: 24 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-03735-21: Section location: Temporal Lobe; Percent tumor nuclei: 80; Percent necrosis: 10.
- Sample C3L-03735-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
